Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7851, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7851-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED] Case ID		[REDACTED] ID	Gross Description	Microscopic Description	Diagnosis Details	Comments
[REDACTED]		[REDACTED]				

[page 2 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy
Tumor site: Fundus
Tumor size: 9 x 6 x 4 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma, intestinal type
Histologic grade: Poorly differentiated
Tumor extent: Serosa (visceral peritoneum)
Lymph nodes: 0/10 positive for metastasis (Regional 0/10)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

OpenClinica ID	Date of Procurement	Laterality

Source: NCI Genomic Data Commons file c2aadad4-694c-492a-8601-99006daeab37 (TCGA-BR-7851.5E808080-B605-4E23-BCC0-290C39167C32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).